Gene-level copy-number profile of tumor specimen TCGA-06-0178-01A from TCGA case TCGA-06-0178, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 39.0 years (14,235 days).
Specimen TCGA-06-0178-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.91553ae1-e549-4e28-9da2-ad0e48e15a31.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0178-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 352 have no estimate.
https://portal.gdc.cancer.gov/files/c6d3183c-244c-4174-88e2-dfb2ed7aded2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,386; copy number 1: 365; copy number 2: 57,353; copy number 3: 39; copy number 4: 25; copy number 5: 103.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 103 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:105,736,343–106,360,324, 103 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 364. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
